Gene-level copy-number profile of tumor specimen TCGA-60-2706-01A from TCGA case TCGA-60-2706, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IA; Age at diagnosis: 58.8 years (21,477 days).
Specimen TCGA-60-2706-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.297d3546-6af3-47ea-b1bf-7ca5f87d0075.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-60-2706-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/d4f3e36a-70f1-4912-8362-d897dbeb62c8

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 37; copy number 1: 28; copy number 2: 17,568; copy number 3: 16,586; copy number 4: 17,959; copy number 5: 3,218; copy number 6: 2,467; copy number 7: 716; copy number 8: 562; copy number 9: 203; copy number 10: 199; copy number 11: 56; copy number 12: 49; copy number 13: 166.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-60-2706-01A-01D-0844-01): tumor purity 0.48, ploidy 3.45, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 37 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr13:46,831,546–47,459,234, 4 genes: HTR2A, HTR2A-AS1, GNG5P5, RN7SL700P.
- chr13:48,232,612–49,691,486, 33 genes (within-gene range 0–4): ITM2B, RB1-DT, RB1, PPP1R26P1, PCNPP5, AL392048.1, LPAR6, Metazoa_SRP, RCBTB2, AL157813.2, AL157813.1, LINC01077, LINC00462, CYSLTR2, PSME2P2, AL161421.1, FNDC3A, RNU6-60P, RAD17P2, RNY3P2, COX7CP1, OGFOD1P1, MLNR, AL137000.1, CDADC1, CAB39L, SETDB2, SNRPGP14, PHF11, RCBTB1, AL135901.1, ARL11, EBPL.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 673 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:167,864,773–174,378,005, 106 genes, copy number 9–10 (broad region; genes not listed).
- chr8:37,326,575–38,853,028, 58 genes, copy number 10–11: AC091182.1, AC091182.2, LINC01605, AC124067.1, AC124067.2, AC124067.3, AC124067.4, AC137579.2, AC137579.1, RNU6-607P, ZNF703, AC138356.3, AC138356.1, ERLIN2, AC138356.2, PLPBP, ADGRA2, BRF2, RAB11FIP1, AC130304.1, RN7SL709P, GOT1L1, AC144573.1, ADRB3, RPL12P48, EIF4EBP1, AP006545.1, AP006545.3, AP006545.2, ASH2L, RNU6-988P, AC084024.1, STAR, AC084024.3, LSM1, RNU6-323P, BAG4, AC084024.2, AC084024.4, DDHD2, PLPP5, NSD3, AC087362.2, AC087362.1, AC087623.2, LETM2, FGFR1, AC087623.3, AC087623.1, RPS20P22, C8orf86, AC069120.1, RNF5P1, AC016813.1, TACC1, Y_RNA, AC067817.1, AC067817.2.
- chr8:76,162,119–78,153,913, 16 genes, copy number 10: AC011029.1, RNU2-54P, AC067773.1, LINC01109, LINC01111, ZFHX4-AS1, AC013509.1, MRPL9P1, ZFHX4, AC011716.1, AC023200.1, MIR3149, PEX2, HIGD1AP18, AC062004.1, AC084706.1.
- chr8:80,485,619–108,626,767, 471 genes, copy number 9–13 (within-gene range 5–13) (broad region; genes not listed).
- chr8:112,148,742–113,436,939, 5 genes, copy number 9 (within-gene range 8–11): RNU4-37P, CSMD3, AC024996.1, RPL30P16, MIR2053.
- chr13:30,456,704–30,617,597, 1 gene, copy number 9 (within-gene range 2–9): HMGB1.
- chr13:30,539,597–31,162,388, 16 genes, copy number 9: RBM22P2, MFAP1P1, PTPN2P2, USPL1, Metazoa_SRP, ALOX5AP, LINC00398, LINC00545, TEX26-AS1, MEDAG, TEX26, AL353680.1, LINC01066, AL158065.1, WDR95P, HSPH1.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
